Gene-level copy-number profile of tumor specimen HCM-SANG-1305-C15-08A-01D-A80T-32 from HCMI case HCM-SANG-1305-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-1305-C15-08A-01D-A80T-32: Sample type: Post neo-adjuvant therapy; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 900f0c16-4b00-437f-9b7e-c4dc05478475.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1305-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/6b0e5467-46d9-440b-b557-c4183daeac66

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 548; copy number 1: 8,334; copy number 2: 32,810; copy number 3: 13,348; copy number 4: 3,065; copy number 5: 576; copy number 6: 45; copy number 7: 3; copy number 8: 75; copy number 10: 22; copy number 12: 61; copy number 14: 14.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,450,245, 3 genes: AC239859.5, RNA5SP533, AC239859.3.
- chr3:11,745–54,346, 2 genes: LINC01986, AC066595.1.
- chr3:60,616,822–60,618,079, 2 genes (within-gene range 0–2): AC104164.2, MIR548BB.
- chr4:4,126,659–4,150,421, 2 genes: OR7E103P, UNC93B4.
- chr4:101,240,795–101,240,872, 1 gene (within-gene range 0–2): MIR8066.
- chr5:6,713,432–6,757,044, 1 gene: TENT4A.
- chr8:18,864,681–18,865,247, 1 gene (within-gene range 0–2): AC087821.1.
- chr15:34,415,450–34,521,791, 4 genes (within-gene range 0–2): AC025678.3, HNRNPLP2, FSCN1P1, DNM1P5.
- chr16:78,825,281–79,017,429, 7 genes (within-gene range 0–2): RPS3P7, AC136603.1, AC027279.4, AC027279.1, AC027279.3, AC027279.2, AC009145.4.
- chr20:14,757,563–14,758,056, 1 gene (within-gene range 0–4): RPS10P2.
- chr20:14,933,843–15,280,873, 4 genes (within-gene range 0–4): AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 796 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–31,109, 5 genes, copy number 10: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2.
- chr1:114,392,790–114,511,203, 4 genes, copy number 5: TRIM33, AL035410.1, EIF2S2P5, Y_RNA.
- chr1:143,498,785–144,305,180, 31 genes, copy number 6: AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1, AC239798.2, FCGR1CP, H2BP2, H3-2, AC246680.1, RPL22P5, FAM72C, SRGAP2D, IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1.
- chr1:149,923,317–151,699,091, 88 genes, copy number 5 (broad region; genes not listed).
- chr1:151,701,026–151,708,386, 1 gene, copy number 5 (within-gene range 4–5): AL589765.1.
- chr1:158,195,633–158,203,877, 2 genes, copy number 7: AL138899.2, AL138899.1.
- chr2:170,640,374–186,422,432, 252 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr2:186,486,253–190,509,205, 51 genes, copy number 5–6 (within-gene range 2–6): ZC3H15, DPRXP1, ITGAV, AC017101.1, FAM171B, ZSWIM2, IMPDH1P7, AC007319.1, RN7SKP42, RNU6-989P, CALCRL, GAPDHP59, TFPI, LINC01090, ST13P2, AC104131.1, RNA5SP114, GULP1, MIR561, AC092598.1, DIRC1, COL3A1, MIR1245A, MIR1245B, MIR3606, COL5A2, AC133106.1, MIR3129, KRT18P19, WDR75, KDM3AP1, SLC40A1, AC012488.1, ASNSD1, ASDURF, AC012488.2, ANKAR, OSGEPL1, OSGEPL1-AS1, AC013468.1, ORMDL1, PMS1, C2orf88, TERF1P6, HNRNPCP2, RNF11P1, MSTN, HIBCH, INPP1, MFSD6, AC093388.1.
- chr2:190,534,855–197,786,762, 88 genes, copy number 5–6 (broad region; genes not listed).
- chr3:196,027,183–198,123,232, 80 genes, copy number 5 (broad region; genes not listed).
- chr6:41,189,749–47,477,572, 167 genes, copy number 8–14 (broad region; genes not listed).
- chr8:123,416,726–123,470,028, 1 gene, copy number 5 (within-gene range 4–5): NTAQ1.
- chr10:38,783,004–38,783,108, 1 gene, copy number 7: AL590623.1.
- chr14:54,938,949–55,191,608, 6 genes, copy number 5: WDHD1, RPSAP13, SOCS4, MAPK1IP1L, LGALS3, DLGAP5.
- chr20:51,596,514–52,204,308, 9 genes, copy number 5: ATP9A, AL138807.1, SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1.
- chr20:53,544,615–54,070,594, 10 genes, copy number 5: Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756.

Autosomal genes at a single copy (total copy number 1): 5,998. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
